Somatic mutation profile of tumor specimen TCGA-BG-A0LX-01A (aliquot TCGA-BG-A0LX-01A-11W-A062-09) from TCGA case TCGA-BG-A0LX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 57.3 years (20,928 days).
Specimen TCGA-BG-A0LX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43129ed5-3cea-4bc1-88b8-80d583e0571a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0LX-10A (Blood Derived Normal), aliquot TCGA-BG-A0LX-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e38726d-a179-4795-83a2-9cfc4919019d

The open-access MAF lists 595 somatic variants for this specimen: 438 protein-altering or splice-affecting, 148 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 286, Silent 148, Frame Shift Del 103, Nonsense Mutation 17, Frame Shift Ins 17, Splice Site 13, Intron 7, In Frame Del 1, 3'Flank 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.1647T>A p.N549K | Missense Mutation (SNP) | VAF 95/111 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913476, COSV60638757, COSV60639738; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.277_292del p.H93* | Frame Shift Del (DEL) | VAF 178/243 reads (73%) | catalogued as rs1554898071; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AAAS | c.545+2T>C p.X182_splice | Splice Site (SNP) | VAF 15/35 reads (43%) | catalogued as COSV52933182; called by muse, mutect2, varscan2
- ABCA1 | c.5928T>C p.S1976= | Splice Region (SNP) | VAF 14/297 reads (5%) | catalogued as COSV66067008; called by muse, mutect2
- ABCC11 | c.3530C>T p.T1177M | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757572924, COSV62323604; called by muse, mutect2, varscan2
- ADAMTS6 | c.1512+2T>A p.X504_splice | Splice Site (SNP) | VAF 13/165 reads (8%) | catalogued as COSV66860460; called by muse, mutect2
- ADAMTSL1 | c.3640T>C p.W1214R | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65892984; called by muse, mutect2, varscan2
- ADAR | c.185C>A p.P62Q | Missense Mutation (SNP) | VAF 77/257 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.012); catalogued as COSV52716300, COSV99425809; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 76/259 reads (29%) | catalogued as rs760140619; called by mutect2, varscan2
- AGR2 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs755871634, COSV68596667; called by muse, mutect2, varscan2
- AMBN | c.1079A>G p.D360G | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs779675904, COSV59826377; called by muse, mutect2, varscan2
- ANKIB1 | c.437dup p.N146Kfs*29 | Frame Shift Ins (INS) | VAF 38/116 reads (33%) | catalogued as rs201434379; called by mutect2, varscan2
- ANKRD27 | c.1389del p.H464Tfs*26 | Frame Shift Del (DEL) | VAF 43/135 reads (32%) | catalogued as rs756222948; called by mutect2, pindel, varscan2
- ANKRD34A | c.1388G>T p.R463M | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV60161095; called by muse, mutect2, varscan2
- APOBEC3D | c.549G>A p.W183* | Nonsense Mutation (SNP) | VAF 112/298 reads (38%) | catalogued as COSV53326921; called by muse, mutect2, varscan2
- APOBEC4 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 81/277 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.259); catalogued as COSV58017801; called by muse, mutect2, varscan2
- APPBP2 | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 52/136 reads (38%) | catalogued as COSV50027061; called by muse, mutect2, varscan2
- ARHGEF5 | c.3907C>T p.R1303C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1305240117, COSV99282549; called by mutect2, varscan2
- ARID1A | c.5980del p.V1994Cfs*21 | Frame Shift Del (DEL) | VAF 144/389 reads (37%) | catalogued as COSV61378965; called by mutect2, pindel, varscan2
- ARIH1 | c.745A>G p.I249V | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV65911722; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.608A>G p.Y203C | Missense Mutation (SNP) | VAF 337/816 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV63438134; called by muse, mutect2, varscan2
- ARNT2 | c.1667C>T p.T556M | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs202101392, COSV57586105; called by muse, mutect2, varscan2
- ASAP1 | c.2558G>A p.G853D | Missense Mutation (SNP) | VAF 11/318 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.234); catalogued as COSV63049345; called by muse, mutect2
- ASH1L | c.8819-1G>T p.X2940_splice (on ENST00000368346 / NM_001366177.2; = p.X2935_splice on NM_018489.3) | Splice Site (SNP) | VAF 90/310 reads (29%) | catalogued as COSV64208738; called by muse, mutect2, varscan2
- ASPM | c.4136C>T p.S1379F | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54125644, COSV54130937; called by muse, mutect2, varscan2
- ATG13 | c.104A>G p.E35G | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV56319791; called by muse, varscan2
- ATG16L1 | c.154T>G p.L52V | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.876); catalogued as COSV61465922; called by muse, mutect2, varscan2
- ATM | c.9007A>G p.N3003D | Missense Mutation (SNP) | VAF 94/266 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1137889, COSV53744107, COSV53761060; called by muse, mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | catalogued as rs1288664341; called by mutect2, pindel, varscan2
- BAHD1 | c.2276A>T p.E759V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60378918; called by muse, mutect2, varscan2
- BBX | c.719G>C p.R240P | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV57885733, COSV57888125; called by muse, mutect2, varscan2
- BIN2 | c.1168C>T p.R390* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as rs761805381, COSV57204327; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 94/267 reads (35%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BPIFB3 | c.387-2A>T p.X129_splice | Splice Site (SNP) | VAF 4/67 reads (6%) | catalogued as COSV64957422; called by muse, mutect2
- BSCL2 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1271994945, COSV54015933; called by muse, mutect2, varscan2
- BTBD1 | c.1377del p.F459Lfs*12 | Frame Shift Del (DEL) | VAF 51/154 reads (33%) | catalogued as rs1567100148; called by mutect2, pindel, varscan2
- C1orf141 | c.13del p.I5Sfs*2 | Frame Shift Del (DEL) | VAF 55/154 reads (36%) | catalogued as rs753677028; called by mutect2, pindel, varscan2
- C2orf16 | c.5063G>A p.S1688N | Missense Mutation (SNP) | VAF 31/610 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as COSV62676152; called by muse, mutect2
- CAD | c.5274G>T p.W1758C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs750241874, COSV53027648; called by muse, mutect2, varscan2
- CAMSAP1 | c.3666del p.V1223Wfs*5 | Frame Shift Del (DEL) | VAF 38/104 reads (37%) | catalogued as COSV100409758; called by mutect2, pindel, varscan2
- CCT8L2 | c.1654dup p.I552Nfs*6 | Frame Shift Ins (INS) | VAF 51/144 reads (35%) | catalogued as rs780034402; called by mutect2, varscan2
- CDC25C | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1019689798, COSV60399698; called by muse, mutect2, varscan2
- CDH10 | c.2187del p.Y730Tfs*19 | Frame Shift Del (DEL) | VAF 111/343 reads (32%) | catalogued as rs1273877423; called by mutect2, pindel, varscan2
- CDH7 | c.2318C>T p.A773V | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59885113; called by muse, mutect2, varscan2
- CENPE | c.5468A>G p.Q1823R | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as COSV54382289; called by muse, mutect2, varscan2
- CEP76 | c.295del p.T99Lfs*90 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs747064410; called by mutect2, varscan2
- CHD7 | c.5604A>G p.I1868M | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.053); catalogued as COSV71111407; called by muse, mutect2
- CHL1 | c.3334T>G p.S1112A (on ENST00000397491 / NM_001253387.1; = p.S1128A on NM_006614.4) | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.669); catalogued as rs200081497, COSV56595017; called by muse, varscan2
- CLSTN3 | c.1993C>A p.P665T | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as rs1378067647, COSV56936838; called by muse, mutect2, varscan2
- CLTCL1 | c.2525C>T p.T842I | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV54232040; called by muse, mutect2
- CNGA1 | c.257T>C p.F86S | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.397); catalogued as COSV62054613; called by muse, mutect2
- CNST | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 71/255 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs373284626; called by muse, mutect2, varscan2
- CNTLN | c.4039G>A p.V1347M | Missense Mutation (SNP) | VAF 79/225 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV52080933; called by muse, mutect2, varscan2
- COL11A1 | c.5102T>G p.L1701R | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62185289; called by muse, mutect2, varscan2
- COL14A1 | c.5374T>C p.W1792R | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV52856554; called by muse, mutect2
- COL22A1 | c.4693G>A p.G1565S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57339932; called by muse, mutect2, varscan2
- COL5A3 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs553969959, COSV53411959; called by muse, mutect2, varscan2
- COPA | c.801T>A p.N267K | Missense Mutation (SNP) | VAF 49/217 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.904); catalogued as COSV54103457; called by muse, mutect2, varscan2
- CPB2 | c.213dup p.V72Cfs*5 | Frame Shift Ins (INS) | VAF 62/178 reads (35%) | catalogued as rs1174947217; called by mutect2, varscan2
- CPED1 | c.2585A>G p.Q862R | Missense Mutation (SNP) | VAF 136/368 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60003862; called by muse, mutect2, varscan2
- CRTAC1 | c.745C>A p.L249I | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.184); catalogued as COSV54002722; called by muse, mutect2, varscan2
- CTAGE1 | c.2069del p.P690Hfs*30 | Frame Shift Del (DEL) | VAF 224/561 reads (40%) | catalogued as rs766584848; called by mutect2, varscan2
- CTCF | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 71/176 reads (40%) | catalogued as COSV50471554; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 235/583 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV54744885; called by muse, mutect2, varscan2
- CXCR5 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52685088; called by muse, mutect2, varscan2
- DCLK1 | c.1673T>C p.I558T | Missense Mutation (SNP) | VAF 124/310 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55190101; called by muse, mutect2, varscan2
- DCPS | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55011179; called by muse, mutect2, varscan2
- DDB1 | c.2609T>C p.V870A | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.354); catalogued as COSV57103262; called by muse, mutect2, varscan2
- DDX3X | c.1892G>T p.R631I (on ENST00000399959; = p.R632I on NM_001356.5) | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.112); catalogued as COSV67863768, COSV67864414, COSV67864628; called by muse, mutect2, varscan2
- DDX42 | c.2578G>A p.G860R | Missense Mutation (SNP) | VAF 96/268 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.559); catalogued as rs146221475; called by muse, mutect2, varscan2
- DDX60L | c.1239del p.P414Lfs*2 | Frame Shift Del (DEL) | VAF 72/230 reads (31%) | catalogued as COSV52714949; called by mutect2, pindel, varscan2
- DENND5B | c.2479G>A p.G827R | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as rs1375658865, COSV60903111; called by muse, mutect2, varscan2
- DGKI | c.2171T>C p.L724P | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs749922562, COSV55938058; called by muse, mutect2, varscan2
- DHRS7C | c.796G>A p.V266M (on ENST00000330255 / NM_001220493.2; = p.V265M on NM_001105571.3) | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs774255168, COSV57651134; called by muse, mutect2, varscan2
- DHX29 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 39/109 reads (36%) | catalogued as rs1298866117, COSV52418776; called by muse, mutect2, varscan2
- DHX35 | c.1913T>C p.I638T | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV52670835; called by muse, mutect2, varscan2
- DIAPH2 | c.461del p.N154Tfs*30 | Frame Shift Del (DEL) | VAF 31/73 reads (42%) | catalogued as COSV61261477; called by mutect2, pindel, varscan2
- DIXDC1 | c.1733G>T p.R578L (on ENST00000440460 / NM_001037954.4; = p.R367L on NM_033425.4) | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV59462146; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 31/94 reads (33%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH2 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs145686578; called by muse, mutect2, varscan2
- DNAH8 | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV59451657; called by muse, mutect2, varscan2
- DNMT1 | c.2895T>A p.D965E | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV61579926; called by muse, varscan2
- DOCK4 | c.5840C>G p.A1947G | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as rs760387414, COSV70237734; called by muse, mutect2, varscan2
- DPAGT1 | c.698del p.F233Sfs*28 | Frame Shift Del (DEL) | VAF 78/172 reads (45%) | catalogued as rs35482889; called by mutect2, varscan2
- DPY19L2 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV60541119, COSV60543766; called by muse, mutect2, varscan2
- DPYSL4 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs768468892, COSV58306285; called by muse, mutect2, varscan2
- DSCAML1 | c.2993G>A p.R998H (on ENST00000321322; = p.R938H on NM_020693.4) | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs750535293, COSV58392253; called by muse, mutect2, varscan2
- DSG1 | c.1840C>T p.P614S | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.243); catalogued as rs762460837, COSV57136128; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1060dup p.W354Lfs*25 | Frame Shift Ins (INS) | VAF 52/164 reads (32%) | catalogued as rs746928635; called by mutect2, varscan2
- DYNC1H1 | c.10676G>A p.R3559H | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777583611, COSV64137707; called by muse, mutect2, varscan2
- DYNC2H1 | c.2786T>C p.L929P | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV62095718; called by muse, mutect2, varscan2
- EDNRB | c.1133T>C p.I378T (on ENST00000377211 / NM_001201397.1; = p.I288T on NM_000115.5) | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); catalogued as COSV57523375; called by muse, mutect2, varscan2
- EFS | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 20/49 reads (41%) | catalogued as rs369126583; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 106/256 reads (41%) | catalogued as rs766700925; called by mutect2, varscan2
- ELP1 | c.2189G>A p.R730Q | Missense Mutation (SNP) | VAF 95/252 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.812); catalogued as rs374558203; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EME1 | c.1148C>A p.A383E | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.322); catalogued as COSV56814645; called by muse, mutect2, varscan2
- ENTR1 | c.1090C>T p.R364* (on ENST00000357365 / NM_001039707.2; = p.R341* on NM_006643.4) | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as rs201271878; called by muse, mutect2, varscan2
- EP300 | c.4886C>T p.A1629V | Missense Mutation (SNP) | VAF 113/283 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54330195; called by muse, mutect2, varscan2
- EPB41L5 | c.802del p.W268Gfs*4 | Frame Shift Del (DEL) | VAF 54/179 reads (30%) | catalogued as rs35675992; called by mutect2, pindel, varscan2
- EPHB2 | c.2446A>G p.M816V (on ENST00000400191 / NM_001309193.2; = p.M817V on NM_004442.7) | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV65863011; called by muse, mutect2, varscan2
- ERCC6 | c.978G>T p.E326D | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV63390814; called by muse, mutect2, varscan2
- EVPL | c.4331T>C p.L1444S | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.511); catalogued as COSV56912013; called by muse, mutect2, varscan2
- FAM133B | c.230G>T p.R77M | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV70075753; called by muse, mutect2
- FAM180A | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.886); catalogued as rs770103665, COSV58528621; called by muse, mutect2, varscan2
- FAM209B | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs767257301, COSV64915309; called by muse, mutect2, varscan2
- FBN3 | c.5828G>A p.G1943D | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV54462761; called by muse, mutect2, varscan2
- FBXO5 | c.878A>G p.Q293R | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.425); catalogued as rs759331223, COSV57671023; called by muse, mutect2, varscan2
- FFAR4 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs1229882352, COSV65179057; called by muse, mutect2, varscan2
- FGD3 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.163); catalogued as rs371917520; called by muse, mutect2, varscan2
- FGF18 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs747503710, COSV51126561, COSV99208553; called by muse, mutect2, varscan2
- FHOD1 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs761027309, COSV50761477; called by muse, mutect2, varscan2
- FLG | c.5341C>T p.R1781C | Missense Mutation (SNP) | VAF 156/494 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs201021216, COSV64239624; called by muse, mutect2, varscan2
- FNDC1 | c.1526T>C p.L509S | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.044); catalogued as rs1344693201, COSV51937280; called by muse, mutect2, varscan2
- FNDC1 | c.4736C>T p.S1579L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs1376511734, COSV51939404; called by muse, mutect2, varscan2
- FYCO1 | c.2075A>G p.K692R | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56116532; called by muse, mutect2, varscan2
- G3BP2 | c.934G>T p.G312* | Nonsense Mutation (SNP) | VAF 50/134 reads (37%) | catalogued as COSV62976523; called by muse, mutect2, varscan2
- GABBR1 | c.1721del p.P574Qfs*32 | Frame Shift Del (DEL) | VAF 74/199 reads (37%) | catalogued as rs777471402; called by mutect2, pindel, varscan2
- GABRA5 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs747206877, COSV59478163; called by muse, mutect2, varscan2
- GDPD5 | c.1417G>A p.V473I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs369648232; called by muse, mutect2, varscan2
- GEMIN7 | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.595); catalogued as COSV54319801; called by muse, mutect2, varscan2
- GNE | c.667G>A p.A223T (on ENST00000396594 / NM_001128227.3; = p.A192T on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV64952072; called by muse, mutect2
- GNL3 | c.1019T>G p.I340S | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56477644; called by muse, mutect2, varscan2
- GOLGA6A | c.151dup p.T51Nfs*2 | Frame Shift Ins (INS) | VAF 27/127 reads (21%) | catalogued as rs764754072; called by mutect2, varscan2
- GPR149 | c.884C>T p.T295I | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1246567249, COSV67667689; called by muse, mutect2, varscan2
- GREB1 | c.5365G>A p.A1789T | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as rs553020411, COSV52188706, COSV99303761; called by muse, mutect2, varscan2
- GRM4 | c.2572C>T p.R858C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs145173138, COSV65214228; called by muse, mutect2, varscan2
- GSDMB | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 15/489 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs1164315955, COSV58345890; called by muse, mutect2
- GSN | c.906+1G>A p.X302_splice | Splice Site (SNP) | VAF 22/61 reads (36%) | catalogued as rs369830648; called by muse, mutect2, varscan2
- GSTM4 | c.490C>A p.L164I | Missense Mutation (SNP) | VAF 79/998 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); catalogued as COSV58694806; called by muse, mutect2
- GUCY1A1 | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as rs1193113289, COSV56652254; called by muse, mutect2, varscan2
- HAND1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV50562696; called by muse, mutect2, varscan2
- HELZ | c.4757G>A p.R1586H | Missense Mutation (SNP) | VAF 100/240 reads (42%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs776661089, COSV62378817; called by muse, mutect2, varscan2
- HERC5 | c.418del p.I140* | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as rs770854785; called by mutect2, varscan2
- HIVEP1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 129/349 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs762780605, COSV65102174; called by muse, mutect2, varscan2
- HIVEP3 | c.1882C>T p.L628F | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV56016455; called by muse, mutect2, varscan2
- HLX | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 92/275 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs199775753, COSV65044930, COSV65045521; called by muse, mutect2, varscan2
- HOXA9 | c.688T>C p.Y230H | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58656203; called by muse, mutect2, varscan2
- HSF4 | c.1325-2A>G p.X442_splice (on ENST00000521374 / NM_001040667.3; = p.X412_splice on NM_001538.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 8/29 reads (28%) | catalogued as COSV50457517; called by muse, mutect2
- HSPH1 | c.2114G>A p.R705Q | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60711771; called by muse, mutect2, varscan2
- HTR5A | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs367704188; called by muse, mutect2, varscan2
- IBTK | c.3448G>T p.G1150* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as COSV60393303; called by muse, mutect2, varscan2
- ICMT | c.767T>A p.I256N | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59473698; called by muse, mutect2, varscan2
- IGHMBP2 | c.2035C>T p.R679W | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs371157210; ClinVar: uncertain significance; called by muse, mutect2
- IKZF1 | c.1228G>A p.G410S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as COSV58786634; called by muse, mutect2, varscan2
- IKZF5 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 81/294 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs375400729; called by muse, mutect2, varscan2
- IL16 | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 61/154 reads (40%) | catalogued as COSV57264208; called by muse, mutect2, varscan2
- IL26 | c.188del p.N63Ifs*5 | Frame Shift Del (DEL) | VAF 101/342 reads (30%) | catalogued as rs778805733; called by mutect2, pindel, varscan2
- INPPL1 | c.1091-1G>C p.X364_splice | Splice Site (SNP) | VAF 9/24 reads (38%) | catalogued as COSV53356202; called by muse, mutect2, varscan2
- INSC | c.1606T>C p.C536R | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65408681; called by muse, mutect2, varscan2
- IQGAP1 | c.2822del p.N941Ifs*8 | Frame Shift Del (DEL) | VAF 86/197 reads (44%) | catalogued as rs771739474; called by mutect2, varscan2
- IQGAP3 | c.3697C>T p.R1233W | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as rs1421071932, COSV63250030; called by muse, mutect2, varscan2
- IRAK4 | c.406A>G p.T136A | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs769345767, COSV71210494; called by muse, mutect2, varscan2
- ISLR2 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV62302364; called by muse, mutect2, varscan2
- ITIH2 | c.2065G>T p.E689* | Nonsense Mutation (SNP) | VAF 28/123 reads (23%) | catalogued as COSV64433478; called by muse, mutect2, varscan2
- IVNS1ABP | c.1803T>G p.I601M | Missense Mutation (SNP) | VAF 153/564 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as COSV62250602, COSV62251222; called by muse, mutect2, varscan2
- JARID2 | c.3358G>A p.A1120T | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV59190529; called by muse, mutect2, varscan2
- JHY | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 98/221 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as rs1248148650, COSV56219741; called by muse, mutect2, varscan2
- KBTBD3 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV73241376; called by muse, mutect2, varscan2
- KCNA5 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.048); catalogued as rs71581016; called by muse, mutect2, varscan2
- KCNK2 | c.1108G>A p.A370T (on ENST00000444842 / NM_001017425.3; = p.A355T on NM_014217.4) | Missense Mutation (SNP) | VAF 85/275 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.269); catalogued as COSV67206615; called by muse, mutect2, varscan2
- KCNV2 | c.1122G>T p.Q374H | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.381); catalogued as COSV66056436; called by muse, mutect2, varscan2
- KIAA1109 | c.7609A>G p.S2537G | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52676003; called by muse, mutect2
- KIAA1217 | c.3536A>T p.N1179I | Missense Mutation (SNP) | VAF 58/242 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as COSV56817616; called by muse, mutect2, varscan2
- KIF13B | c.2519T>G p.L840R | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV72879494; called by muse, mutect2, varscan2
- KIF4A | c.2165G>A p.R722Q | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs779212620, COSV65543637; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIRREL1 | c.1009del p.L337Sfs*14 | Frame Shift Del (DEL) | VAF 125/477 reads (26%) | catalogued as rs754171400, COSV63285253; called by mutect2, pindel, varscan2
- KIRREL2 | c.1953dup p.C652Lfs*49 | Frame Shift Ins (INS) | VAF 20/52 reads (38%) | catalogued as rs761116739; called by mutect2, varscan2
- KMO | c.939del p.F313Lfs*5 | Frame Shift Del (DEL) | VAF 70/250 reads (28%) | catalogued as rs760795658; called by mutect2, pindel, varscan2
- KNOP1 | c.652del p.I218Sfs*41 | Frame Shift Del (DEL) | VAF 43/118 reads (36%) | catalogued as rs764099275; called by mutect2, varscan2
- KPRP | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1175728082, COSV64221236; called by muse, mutect2, varscan2
- KRT85 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV57737109; called by muse, mutect2, varscan2
- KSR1 | c.2254G>A p.D752N (on ENST00000644974 / NM_001367810.1; = p.D637N on NM_014238.2) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); catalogued as rs758553199, COSV52032126; called by muse, mutect2, varscan2
- L3MBTL4 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 115/275 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs756896807, COSV53124895; called by muse, mutect2, varscan2
- LARP1B | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 36/98 reads (37%) | catalogued as COSV52798279, COSV52802302; called by muse, mutect2, varscan2
- LGALS9 | c.1037del p.G346Afs*5 (on ENST00000395473 / NM_009587.3; = p.G314Afs*5 on NM_002308.4) | Frame Shift Del (DEL) | VAF 44/120 reads (37%) | catalogued as rs775745717; called by mutect2, pindel, varscan2
- LILRA5 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs374335118, COSV56642976; called by muse, mutect2, varscan2
- LIN7C | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 49/162 reads (30%) | catalogued as rs199824050; called by muse, mutect2, varscan2
- LINGO4 | c.787A>G p.N263D | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63214005, COSV63214879; called by muse, mutect2, varscan2
- LUZP1 | c.989A>G p.Q330R | Missense Mutation (SNP) | VAF 159/352 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as rs1018603810, COSV56501670; called by muse, mutect2, varscan2
- MACF1 | c.14686del p.T4896Lfs*29 (on ENST00000372915; = p.T2829Lfs*29 on NM_012090.5) | Frame Shift Del (DEL) | VAF 68/153 reads (44%) | catalogued as rs775539898; called by mutect2, varscan2
- MAN2A1 | c.1916del p.N639Ifs*2 | Frame Shift Del (DEL) | VAF 6/13 reads (46%) | catalogued as rs758700583; called by mutect2, varscan2
- MAP2 | c.5312del p.R1771Lfs*100 | Frame Shift Del (DEL) | VAF 43/125 reads (34%) | catalogued as COSV52293410, COSV99557394; called by mutect2, pindel, varscan2
- MAP2K6 | c.331T>A p.F111I | Missense Mutation (SNP) | VAF 102/240 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as COSV63006242; called by muse, mutect2, varscan2
- MAPK3 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV53774085; called by muse, mutect2, varscan2
- MAPKAP1 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.828); catalogued as rs1371596131, COSV56367318, COSV56372183; called by muse, mutect2, varscan2
- MCM4 | c.1140C>A p.D380E | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.2); catalogued as COSV50624211; called by muse, mutect2
- MDH1 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs756849053, COSV51863719; called by muse, mutect2, varscan2
- MDH1B | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65590076; called by muse, varscan2
- MDN1 | c.14662G>T p.D4888Y | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV65522772; called by muse, mutect2, varscan2
- MDN1 | c.12866G>A p.R4289H | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.719); catalogued as rs762837284, COSV65522779; called by muse, mutect2, varscan2
- MEGF10 | c.545G>C p.C182S | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57250206; called by muse, mutect2, varscan2
- METTL17 | c.349T>A p.F117I | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1268509911, COSV59556226; called by muse, mutect2, varscan2
- MFGE8 | c.89del p.N30Tfs*64 | Frame Shift Del (DEL) | VAF 25/72 reads (35%) | catalogued as COSV51555063; called by mutect2, pindel, varscan2
- MIS18BP1 | c.471del p.K157Nfs*24 | Frame Shift Del (DEL) | VAF 56/107 reads (52%) | catalogued as rs546807245; called by mutect2, varscan2
- MMADHC | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57573792; called by muse, mutect2, varscan2
- MORN5 | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 7/164 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101055636, COSV65649026; called by muse, mutect2
- MS4A6E | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 87/223 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55727138; called by muse, mutect2, varscan2
- MTMR9 | c.212T>C p.I71T | Missense Mutation (SNP) | VAF 102/253 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs1398043817, COSV55312901; called by muse, mutect2, varscan2
- MUC16 | c.1066T>C p.S356P | Missense Mutation (SNP) | VAF 104/273 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); catalogued as rs1346764490, COSV67470813; called by muse, mutect2, varscan2
- MYO10 | c.4928G>A p.R1643Q | Missense Mutation (SNP) | VAF 65/192 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs753633171, COSV57021525, COSV57022846; called by muse, mutect2, varscan2
- MYO1B | c.1637G>A p.S546N | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1163097235, COSV58431914; called by muse, mutect2, varscan2
- MYO3A | c.4723A>G p.N1575D | Missense Mutation (SNP) | VAF 13/214 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV56333529; called by muse, mutect2
- MYO9A | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 88/213 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61852010; called by muse, mutect2, varscan2
- NAP1L5 | c.462G>C p.E154D | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV52020776; called by muse, mutect2, varscan2
- NAT8 | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55542667; called by muse, mutect2, varscan2
- NBEA | c.7282A>G p.T2428A | Missense Mutation (SNP) | VAF 65/184 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1237912982, COSV59789813; called by muse, mutect2, varscan2
- NCKIPSD | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.277); catalogued as COSV53661699; called by muse, mutect2, varscan2
- NCOR1 | c.5264G>A p.R1755H | Missense Mutation (SNP) | VAF 121/278 reads (44%) | SIFT tolerated (0.79); PolyPhen benign (0.033); catalogued as rs1265372042, COSV51977248; called by muse, mutect2, varscan2
- NDE1 | c.1037C>T p.T346I (on ENST00000577101; = p.D318= on NM_017668.3) | Missense Mutation (SNP) | VAF 40/97 reads (41%) | PolyPhen possibly damaging (0.711); catalogued as COSV55555547; called by muse, mutect2, varscan2
- NDUFAF1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780883829, COSV52975568; called by muse, mutect2, varscan2
- NEK3 | c.598C>T p.H200Y | Missense Mutation (SNP) | VAF 223/549 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs1352182285, COSV51617330; called by muse, mutect2, varscan2
- NLGN3 | c.2341dup p.H781Pfs*2 (on ENST00000358741 / NM_181303.2; = p.H761Pfs*2 on NM_018977.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 10/42 reads (24%) | catalogued as rs760052938; called by mutect2, varscan2
- NLRP1 | c.3601G>T p.E1201* | Nonsense Mutation (SNP) | VAF 23/67 reads (34%) | catalogued as COSV52568000; called by muse, mutect2, varscan2
- NLRP7 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.198); catalogued as COSV60175633; called by muse, mutect2, varscan2
- NPFFR2 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as rs368305828, COSV58153566; called by muse, mutect2, varscan2
- NR1D2 | c.772A>T p.T258S | Missense Mutation (SNP) | VAF 87/196 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.074); catalogued as COSV56992209; called by muse, mutect2, varscan2
- NSMAF | c.2053G>A p.A685T | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV50688290; called by muse, mutect2, varscan2
- NSRP1 | c.507A>C p.E169D | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); catalogued as COSV55934080; called by muse, mutect2, varscan2
- NUFIP1 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752532973, COSV64791247; called by muse, mutect2, varscan2
- NUP88 | c.377T>C p.I126T | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs144721034; called by muse, mutect2, varscan2
- OAS3 | c.644T>C p.L215P | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV57446236; called by muse, mutect2, varscan2
- OBSCN | c.15542G>A p.G5181D | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as rs560771726, COSV52781428; called by muse, mutect2, varscan2
- OFD1 | c.1087A>G p.I363V | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV60796335; called by muse, mutect2
- OGDH | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56050941; called by muse, mutect2
- OLFML2B | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54196886; called by muse, mutect2, varscan2
- ONECUT1 | c.953G>T p.R318M | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59949156; called by muse, mutect2, varscan2
- OR3A2 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 115/293 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as COSV68695111; called by muse, mutect2
- OR51G1 | c.609T>G p.F203L | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV58969488; called by muse, mutect2, varscan2
- PATZ1 | c.1480A>G p.S494G | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0.3); catalogued as rs1257859719, COSV53229711; called by muse, mutect2, varscan2
- PCDHGA12 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.166); catalogued as COSV52754284; called by muse, mutect2, varscan2
- PDILT | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 142/364 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as rs191618493; called by muse, mutect2, varscan2
- PEAK1 | c.2993G>A p.G998D | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as rs776389695, COSV56936804; called by muse, mutect2, varscan2
- PFAS | c.1403C>A p.S468Y | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58980831; called by muse, mutect2, varscan2
- PIK3C2A | c.5033A>G p.Y1678C | Missense Mutation (SNP) | VAF 97/254 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1265041141, COSV56403496; called by muse, mutect2, varscan2
- PKHD1 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as COSV61878945; called by muse, mutect2
- PLCB2 | c.662T>C p.I221T | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53034278; called by muse, mutect2, varscan2
- PLCE1 | c.2705C>T p.A902V | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.054); catalogued as COSV53353231; called by muse, mutect2, varscan2
- PLEKHG1 | c.2612G>T p.R871M | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV62047923; called by muse, mutect2, varscan2
- PLIN2 | c.251G>A p.C84Y | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV52803406; called by muse, mutect2, varscan2
- PLXNB1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56490518; called by muse, mutect2, varscan2
- PLXNC1 | c.4318G>A p.G1440S | Missense Mutation (SNP) | VAF 103/249 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as rs776462415, COSV51576377; called by muse, mutect2, varscan2
- POLE | c.5094G>T p.E1698D | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV57681828; called by muse, mutect2, varscan2
- POSTN | c.1022A>G p.N341S | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV65713200, COSV65713229; called by muse, mutect2, varscan2
- PPARG | c.109C>T p.P37S (on ENST00000287820 / NM_015869.5; = p.P7S on NM_005037.7) | Missense Mutation (SNP) | VAF 9/280 reads (3%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.294); catalogued as COSV104382545, COSV55140996; called by muse, mutect2
- PPIG | c.998T>A p.I333N | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53643598; called by muse, mutect2, varscan2
- PPP1R3F | c.1855C>A p.P619T | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV50018641; called by muse, mutect2, varscan2
- PPRC1 | c.2614C>T p.P872S | Missense Mutation (SNP) | VAF 77/234 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs916317520, COSV53385888; called by muse, mutect2, varscan2
- PRKACA | c.574del p.V192* | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as COSV58068191; called by mutect2, varscan2
- PRKAR1B | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64318822, COSV64319752; called by muse, mutect2, varscan2
- PRRX1 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs747075971, COSV53414416; called by muse, mutect2, varscan2
- PSMA2 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as COSV55030970, COSV55031353; called by muse, mutect2, varscan2
- PTCH2 | c.2033C>T p.P678L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752642110, COSV64711416; called by muse, mutect2
- PTGFRN | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 342/811 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); catalogued as rs1456853077, COSV67797579; called by muse, mutect2, varscan2
- PTPRO | c.1133A>G p.D378G | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV55511979; called by muse, mutect2
- RAD23B | c.1148T>C p.V383A | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63658817; called by muse, mutect2, varscan2
- RAPH1 | c.50G>A p.S17N | Missense Mutation (SNP) | VAF 85/220 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV57354074; called by muse, mutect2, varscan2
- RBBP8 | c.1071del p.K357Nfs*3 | Frame Shift Del (DEL) | VAF 70/171 reads (41%) | catalogued as rs754547584, COSV59093143; ClinVar: uncertain significance; called by mutect2, varscan2
- RBL1 | c.3034A>G p.K1012E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.708); catalogued as COSV60330309; called by muse, mutect2, varscan2
- RBM26 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as rs1482346053, COSV57395192; called by muse, mutect2, varscan2
- RBM45 | c.1149del p.A384Lfs*7 (on ENST00000616198 / NM_001365579.1; = p.A382Lfs*7 on NM_152945.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 51/118 reads (43%) | catalogued as rs749563266; called by mutect2, varscan2
- RERE | c.1511G>T p.G504V | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV61943206; called by muse, mutect2
- RGR | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.939); catalogued as rs1308203557, COSV63894190; called by muse, mutect2, varscan2
- RHPN2 | c.1777C>T p.L593F | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.268); catalogued as COSV54279712; called by muse, mutect2, varscan2
- RLF | c.5494A>G p.S1832G | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV65652095; called by muse, mutect2, varscan2
- RNASEL | c.1225C>T p.Q409* | Nonsense Mutation (SNP) | VAF 121/489 reads (25%) | catalogued as rs563565046, COSV62377016; called by muse, mutect2, varscan2
- RNF144A | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 83/200 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as rs768495307, COSV57982886; called by muse, mutect2, varscan2
- RNF43 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.154); catalogued as COSV68458494; called by muse, mutect2, varscan2
- ROBO4 | c.1255C>T p.Q419* | Nonsense Mutation (SNP) | VAF 24/53 reads (45%) | catalogued as COSV60624654; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 46/111 reads (41%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KA3 | c.1727T>C p.M576T | Missense Mutation (SNP) | VAF 120/320 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as COSV101084293, COSV65388034; called by muse, mutect2, varscan2
- RPS6KA5 | c.1820G>C p.S607T | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56222437; called by muse, mutect2, varscan2
- RYR1 | c.3164C>A p.P1055H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV100615337, COSV62099354; called by muse, mutect2, varscan2
- RYR2 | c.4754G>A p.R1585H | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1392451418, COSV63661428; called by muse, mutect2, varscan2
- RYR3 | c.4724G>A p.R1575H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs767831680, COSV66792748; called by muse, mutect2, varscan2
- SAMD15 | c.302C>A p.P101Q | Missense Mutation (SNP) | VAF 326/810 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV53626576; called by muse, mutect2, varscan2
- SASS6 | c.1319A>T p.E440V | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV54928244; called by muse, mutect2, varscan2
- SEC24B | c.747C>A p.H249Q | Missense Mutation (SNP) | VAF 111/289 reads (38%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV54500349; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 40/95 reads (42%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEPTIN7 | c.1300G>T p.G434W | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV63255286; called by muse, mutect2
- SHISA2 | c.488C>T p.T163I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60110988; called by muse, mutect2, varscan2
- SHISAL1 | c.164C>T p.T55I | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV66988041; called by muse, mutect2, varscan2
- SHROOM3 | c.64A>G p.K22E | Missense Mutation (SNP) | VAF 16/303 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV56030692; called by muse, mutect2
- SIGLEC6 | c.842del p.P281Lfs*4 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | catalogued as COSV100585657; called by mutect2, pindel, varscan2
- SIK3 | c.4003T>C p.S1335P (on ENST00000445177 / NM_001366686.2; = p.S1293P on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.159); catalogued as COSV52615527; called by muse, mutect2, varscan2
- SIPA1L3 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372329721; called by muse, mutect2
- SIX1 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as rs1051653507, COSV55959790; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A15 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV58556840; called by muse, mutect2, varscan2
- SLC29A3 | c.1207C>T p.H403Y | Missense Mutation (SNP) | VAF 77/278 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV64385250; called by muse, mutect2, varscan2
- SLC2A13 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201171876, COSV55118087; called by muse, mutect2, varscan2
- SLC2A9 | c.1406T>C p.F469S | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53316855; called by muse, mutect2, varscan2
- SLC38A5 | c.740G>A p.C247Y | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV58334475; called by muse, mutect2, varscan2
- SLC5A8 | c.1655C>A p.P552H | Missense Mutation (SNP) | VAF 90/215 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV73310732; called by muse, mutect2, varscan2
- SLC5A9 | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.896); catalogued as COSV52583892; called by muse, mutect2, varscan2
- SLC6A14 | c.126del p.K42Nfs*8 | Frame Shift Del (DEL) | VAF 84/255 reads (33%) | catalogued as COSV100903217; called by mutect2, pindel, varscan2
- SLC9A5 | c.1769G>A p.R590H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs372898190; called by muse, mutect2
- SLK | c.2671C>T p.R891C | Missense Mutation (SNP) | VAF 133/428 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753650385, COSV59825952; called by muse, mutect2, varscan2
- SMARCA2 | c.4165G>A p.A1389T | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs769712929, COSV56647053; called by muse, mutect2, varscan2
- SMOX | c.934T>C p.S312P | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53865409; called by muse, mutect2, varscan2
- SMYD5 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs1429604796, COSV50265041; called by muse, mutect2, varscan2
- SNTG2 | c.194G>A p.S65N | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.143); catalogued as COSV57986784; called by muse, mutect2, varscan2
- SOBP | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as rs1263646072, COSV57998652; called by muse, mutect2, varscan2
- SP140 | c.782A>G p.Y261C | Missense Mutation (SNP) | VAF 224/594 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.087); catalogued as rs1406951382, COSV59450644; called by muse, mutect2, varscan2
- SP140 | c.1731G>T p.K577N | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as COSV59450666; called by muse, mutect2, varscan2
- SP140 | c.1933C>T p.R645C | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs199553029, COSV59450674; called by muse, mutect2, varscan2
- SPIRE1 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs149161859; called by muse, mutect2, varscan2
- STAB2 | c.4756C>T p.P1586S | Missense Mutation (SNP) | VAF 255/591 reads (43%) | SIFT tolerated (0.77); PolyPhen benign (0.026); catalogued as COSV66340205; called by muse, mutect2, varscan2
- SWT1 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs560126251, COSV62255643; called by muse, mutect2, varscan2
- SYCP3 | c.626C>A p.A209D | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV57149249; called by muse, mutect2, varscan2
- SYT10 | c.1296G>T p.E432D | Missense Mutation (SNP) | VAF 89/214 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV57341227; called by muse, mutect2, varscan2
- TAAR5 | c.325C>A p.L109M | Missense Mutation (SNP) | VAF 83/196 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV57799166; called by muse, mutect2, varscan2
- TAB1 | c.836A>G p.D279G | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as COSV53371622; called by muse, mutect2, varscan2
- TATDN2 | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.443); catalogued as COSV55052270; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 31/93 reads (33%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TDRD1 | c.1432G>A p.V478I | Missense Mutation (SNP) | VAF 64/119 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs906904597, COSV52589658; called by muse, mutect2, varscan2
- TELO2 | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV51978232; called by muse, mutect2, varscan2
- TEX10 | c.1747C>T p.R583* | Nonsense Mutation (SNP) | VAF 65/153 reads (42%) | catalogued as COSV66515241; called by muse, mutect2, varscan2
- TEX2 | c.860T>A p.I287N | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV51981788; called by muse, mutect2, varscan2
- THOC2 | c.2768A>G p.K923R | Missense Mutation (SNP) | VAF 107/268 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV55547346; called by muse, mutect2, varscan2
- TMC4 | c.460+1del p.X154_splice (on ENST00000617472 / NM_001145303.3; = p.X148_splice on NM_144686.4) | Splice Site (DEL) | VAF 35/125 reads (28%) | catalogued as rs769838894; called by mutect2, pindel, varscan2
- TMEM108 | c.1660A>G p.M554V | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV56589228; called by muse, mutect2, varscan2
- TMEM132D | c.2487del p.K829Nfs*44 | Frame Shift Del (DEL) | VAF 62/238 reads (26%) | catalogued as COSV67159713; called by mutect2, pindel, varscan2
- TMEM135 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs1397258576, COSV59700809; called by muse, mutect2, varscan2
- TMEM25 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57096935; called by muse, mutect2, varscan2
- TMEM97 | c.528del p.K176Nfs*188 | Frame Shift Del (DEL) | VAF 56/135 reads (41%) | catalogued as rs781830688; called by mutect2, varscan2
- TNFRSF10B | c.144+2T>C p.X48_splice | Splice Site (SNP) | VAF 5/9 reads (56%) | catalogued as COSV52392739; called by muse, mutect2, varscan2
- TNN | c.1795C>T p.H599Y | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs781503358, COSV53427734; called by muse, mutect2, varscan2
- TOR1A | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as rs775770765, COSV61029206; called by muse, mutect2, varscan2
- TRAPPC10 | c.1462T>C p.F488L | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV52377947; called by muse, mutect2, varscan2
- TRIM5 | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 237/650 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as COSV59900302; called by muse, mutect2, varscan2
- TRIP12 | c.2654+1G>A p.X885_splice | Splice Site (SNP) | VAF 37/93 reads (40%) | catalogued as COSV52264866; called by muse, mutect2, varscan2
- TRPC6 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 74/184 reads (40%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); catalogued as COSV60255673; called by muse, mutect2
- TRPC7 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV61458570; called by muse, mutect2, varscan2
- TRPM1 | c.3901del p.T1301Pfs*6 | Frame Shift Del (DEL) | VAF 120/348 reads (34%) | catalogued as rs765296730; called by mutect2, pindel, varscan2
- TRRAP | c.8341G>A p.E2781K (on ENST00000359863 / NM_001244580.1; = p.E2763K on NM_003496.3) | Missense Mutation (SNP) | VAF 5/110 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as rs1440331102, COSV62845931; called by muse, mutect2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.68504A>G p.E22835G (on ENST00000591111; = p.E15411G on NM_003319.4) | Missense Mutation (SNP) | VAF 56/135 reads (41%) | PolyPhen possibly damaging (0.621); catalogued as COSV60107217; called by muse, mutect2, varscan2
- TTN | c.39169A>G p.I13057V (on ENST00000591111; = p.I5633V on NM_003319.4) | Missense Mutation (SNP) | VAF 43/106 reads (41%) | PolyPhen probably damaging (0.978); catalogued as COSV60107239; called by muse, mutect2, varscan2
- UBR4 | c.6072+2T>C p.X2024_splice | Splice Site (SNP) | VAF 94/254 reads (37%) | catalogued as COSV64391080; called by muse, mutect2, varscan2
- UGT2B11 | c.756del p.A253Lfs*60 | Frame Shift Del (DEL) | VAF 114/324 reads (35%) | catalogued as rs752853799; called by mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 32/75 reads (43%) | catalogued as rs767420916; called by mutect2, varscan2
- UTP20 | c.7747G>A p.E2583K | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1203248857, COSV55378355; called by muse, mutect2, varscan2
- UTRN | c.3841C>T p.R1281C | Missense Mutation (SNP) | VAF 94/225 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770868827, COSV62337135; called by muse, mutect2, varscan2
- VAMP8 | c.224A>T p.K75M | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55705418; called by muse, mutect2
- VASP | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs571015875, COSV55606956; called by muse, mutect2, varscan2
- VEGFD | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as COSV52909850; called by muse, mutect2, varscan2
- VIM | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV56406028; called by muse, mutect2, varscan2
- VIRMA | c.1877G>T p.R626M | Missense Mutation (SNP) | VAF 109/230 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV52585858; called by muse, mutect2, varscan2
- VPS50 | c.1681A>C p.S561R | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV58508074; called by muse, mutect2, varscan2
- VPS53 | c.1978C>T p.R660C (on ENST00000571805 / NM_001366253.2; = p.R631C on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs942578541, COSV52131738; called by muse, mutect2, varscan2
- VWA3A | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774229691, COSV55391498; called by muse, mutect2, varscan2
- VWF | c.7479G>T p.R2493S | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs1174500026, COSV54622529; called by muse, mutect2, varscan2
- WDR3 | c.580-1G>T p.X194_splice | Splice Site (SNP) | VAF 100/285 reads (35%) | catalogued as COSV62523532; called by muse, mutect2, varscan2
- WIPF1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV55810997; called by muse, mutect2, varscan2
- XPO6 | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs1050148366, COSV58967217; called by muse, mutect2, varscan2
- ZBTB45 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs139000061; called by muse, mutect2, varscan2
- ZC3H18 | c.2406del p.Q804Sfs*15 | Frame Shift Del (DEL) | VAF 23/72 reads (32%) | catalogued as rs750724166; called by mutect2, pindel, varscan2
- ZEB2 | c.1862T>C p.V621A | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as CD053624, COSV57951835; called by muse, mutect2, varscan2
- ZFAT | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs369173147; called by muse, mutect2, varscan2
- ZFP69 | c.85del p.A29Rfs*7 | Frame Shift Del (DEL) | VAF 47/152 reads (31%) | catalogued as COSV65528879, COSV65529298; called by mutect2, pindel, varscan2
- ZGRF1 | c.2923A>G p.M975V | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs970640363, COSV52201049; called by muse, mutect2
- ZHX3 | c.2392A>G p.M798V | Missense Mutation (SNP) | VAF 78/205 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760061000, COSV58384109; called by muse, mutect2, varscan2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs753611080; called by mutect2, varscan2
- ZNF12 | c.200G>T p.W67L | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61244471; called by muse, mutect2, varscan2
- ZNF236 | c.1381del p.M461* | Frame Shift Del (DEL) | VAF 117/291 reads (40%) | catalogued as rs769237443, COSV53487827; called by mutect2, varscan2
- ZNF311 | c.1610G>A p.S537N | Missense Mutation (SNP) | VAF 97/260 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV65853146; called by muse, mutect2, varscan2
- ZNF532 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 135/313 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60173501; called by muse, mutect2, varscan2
- ZNF574 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 122/287 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.831); catalogued as rs111308949, COSV55904066; called by muse, mutect2, varscan2
- ZNF675 | c.1354T>C p.Y452H | Missense Mutation (SNP) | VAF 72/213 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV63096262; called by muse, mutect2, varscan2
- ABCB1 | c.602del p.F201Sfs*5 | Frame Shift Del (DEL) | VAF 86/286 reads (30%) | called by mutect2, pindel, varscan2
- AC100868.1 | c.1494del p.A499Pfs*18 | Frame Shift Del (DEL) | VAF 28/82 reads (34%) | called by mutect2, pindel, varscan2
- ADCY6 | c.3466del p.E1156Rfs*2 | Frame Shift Del (DEL) | VAF 24/96 reads (25%) | called by mutect2, pindel, varscan2
- AKAP9 | c.5920del p.T1974Lfs*3 (on ENST00000359028; = p.T1942Lfs*3 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 64/207 reads (31%) | called by mutect2, pindel, varscan2
- ALPK2 | c.4879dup p.M1627Nfs*5 | Frame Shift Ins (INS) | VAF 12/136 reads (9%) | called by mutect2, pindel
- ANKRD26 | c.527dup p.N176Kfs*4 | Frame Shift Ins (INS) | VAF 25/116 reads (22%) | called by pindel, varscan2
- AP3B1 | c.1789del p.I597Yfs*3 | Frame Shift Del (DEL) | VAF 26/85 reads (31%) | called by mutect2, varscan2
- ARHGAP29 | c.1763del p.P588Lfs*18 | Frame Shift Del (DEL) | VAF 138/409 reads (34%) | called by mutect2, pindel, varscan2
- ATP9A | c.545del p.N182Tfs*71 | Frame Shift Del (DEL) | VAF 40/94 reads (43%) | called by mutect2, varscan2
- BCL11A | c.691del p.L231Cfs*15 (on ENST00000335712 / NM_001365609.1; = p.L265Cfs*15 on NM_018014.4) | Frame Shift Del (DEL) | VAF 22/59 reads (37%) | called by mutect2, pindel, varscan2
- CACNA1E | c.3016del p.L1006* | Frame Shift Del (DEL) | VAF 36/167 reads (22%) | called by mutect2, pindel, varscan2
- CATSPERE | c.1613_1615del p.T538del | In Frame Del (DEL) | VAF 33/160 reads (21%) | called by pindel, varscan2
- CCNK | c.1109del p.P370Hfs*13 | Frame Shift Del (DEL) | VAF 83/282 reads (29%) | called by mutect2, pindel, varscan2
- CDH17 | c.925del p.Y309Mfs*20 | Frame Shift Del (DEL) | VAF 93/261 reads (36%) | called by mutect2, pindel, varscan2
- CEP128 | c.815del p.N272Ifs*3 | Frame Shift Del (DEL) | VAF 79/203 reads (39%) | called by mutect2, pindel, varscan2
- CTCF | c.610del p.T204Qfs*18 | Frame Shift Del (DEL) | VAF 84/207 reads (41%) | called by mutect2, varscan2
- CUL5 | c.1005+2dup p.X335_splice | Splice Site (INS) | VAF 29/71 reads (41%) | called by mutect2, pindel, varscan2
- DEPDC1B | c.234del p.K78Nfs*3 | Frame Shift Del (DEL) | VAF 145/466 reads (31%) | called by mutect2, pindel, varscan2
- DMAC2L | c.340del p.I114* | Frame Shift Del (DEL) | VAF 52/137 reads (38%) | called by mutect2, pindel, varscan2
- DST | c.13273del p.T4425Hfs*7 (on ENST00000361203 / NM_001374722.1; = p.T2013Hfs*7 on NM_015548.5) | Frame Shift Del (DEL) | VAF 37/103 reads (36%) | called by mutect2, pindel, varscan2
- DYSF | c.3225del p.F1075Lfs*45 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | called by mutect2, pindel, varscan2
- EIF5B | c.447del p.A150Lfs*31 | Frame Shift Del (DEL) | VAF 90/249 reads (36%) | called by mutect2, pindel, varscan2
- EPS15 | c.1859del p.F620Sfs*66 | Frame Shift Del (DEL) | VAF 55/169 reads (33%) | called by mutect2, pindel, varscan2
- FAT3 | c.9701del p.P3234Lfs*10 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by mutect2, pindel, varscan2
- FYB1 | c.703del p.S235Afs*4 | Frame Shift Del (DEL) | VAF 127/371 reads (34%) | called by mutect2, pindel, varscan2
- GAK | c.1472dup p.N491Kfs*71 | Frame Shift Ins (INS) | VAF 7/13 reads (54%) | called by mutect2, varscan2
- GGT6 | c.338dup p.A114Cfs*44 (on ENST00000574154 / NM_001122890.3; = p.A114Cfs*12 on NM_153338.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | called by mutect2, varscan2
- GRID2 | c.1376del p.N459Mfs*32 | Frame Shift Del (DEL) | VAF 31/109 reads (28%) | called by mutect2, pindel, varscan2
- GULP1 | c.754del p.D252Tfs*26 | Frame Shift Del (DEL) | VAF 28/103 reads (27%) | called by mutect2, pindel, varscan2
- HEATR1 | c.5937del p.F1979Lfs*18 | Frame Shift Del (DEL) | VAF 69/289 reads (24%) | called by mutect2, pindel, varscan2
- HNRNPD | c.550del p.I184Ffs*15 | Frame Shift Del (DEL) | VAF 26/79 reads (33%) | called by mutect2, pindel, varscan2
- IDE | c.1706dup p.L569Ffs*9 | Frame Shift Ins (INS) | VAF 19/80 reads (24%) | called by mutect2, varscan2
- IGSF1 | c.28del p.A10Pfs*4 | Frame Shift Del (DEL) | VAF 54/138 reads (39%) | called by mutect2, pindel, varscan2
- INPPL1 | c.2927del p.P976Hfs*155 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- INTS2 | c.695dup p.N232Kfs*7 | Frame Shift Ins (INS) | VAF 190/550 reads (35%) | called by mutect2, pindel, varscan2
- LATS1 | c.927del p.M310* | Frame Shift Del (DEL) | VAF 76/479 reads (16%) | called by mutect2, pindel, varscan2
- LRP12 | c.1340dup p.N447Kfs*13 | Frame Shift Ins (INS) | VAF 46/174 reads (26%) | called by mutect2, varscan2
- LTBR | c.543del p.S182Afs*33 | Frame Shift Del (DEL) | VAF 58/182 reads (32%) | called by mutect2, pindel, varscan2
- MAPT | c.83del p.G28Afs*16 | Frame Shift Del (DEL) | VAF 31/76 reads (41%) | called by mutect2, pindel, varscan2
- MEIOC | c.1744del p.I582* | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | called by mutect2, pindel, varscan2
- MORC4 | c.847del p.I283Ffs*8 | Frame Shift Del (DEL) | VAF 116/329 reads (35%) | called by mutect2, pindel, varscan2
- MROH1 | c.1387C>G p.R463G | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- NBPF10 | c.11312_11337del p.V3771Gfs*21 | Frame Shift Del (DEL) | VAF 73/505 reads (14%) | called by mutect2, pindel, varscan2
- NCOA4 | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- NELFB | c.707del p.F236Sfs*17 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, varscan2
- NSD1 | c.4591del p.M1531Cfs*43 | Frame Shift Del (DEL) | VAF 27/66 reads (41%) | called by mutect2, pindel, varscan2
- NUCB2 | c.1200del p.K400Nfs*15 | Frame Shift Del (DEL) | VAF 27/73 reads (37%) | called by mutect2, varscan2
- OBSL1 | c.4291_4292del p.L1431Afs*122 | Frame Shift Del (DEL) | VAF 53/174 reads (30%) | called by mutect2, pindel, varscan2
- OR5D18 | c.800del p.N267Tfs*16 | Frame Shift Del (DEL) | VAF 88/257 reads (34%) | called by mutect2, pindel, varscan2
- PARPBP | c.417del p.K139Nfs*5 | Frame Shift Del (DEL) | VAF 46/157 reads (29%) | called by mutect2, pindel, varscan2
- PCDH15 | c.5388del p.P1797Hfs*47 | Frame Shift Del (DEL) | VAF 25/127 reads (20%) | called by mutect2, pindel, varscan2
- PCNX2 | c.4168del p.Y1390Mfs*4 | Frame Shift Del (DEL) | VAF 36/109 reads (33%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1701dup p.P568Tfs*34 (on ENST00000521381 / NM_181523.3; = p.P298Tfs*34 on NM_181504.4) | Frame Shift Ins (INS) | VAF 67/231 reads (29%) | called by mutect2, pindel, varscan2
- PLAGL2 | c.30del p.W11Gfs*15 | Frame Shift Del (DEL) | VAF 41/126 reads (33%) | called by mutect2, pindel, varscan2
- PXDN | c.2592del p.N865Mfs*25 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | called by mutect2, varscan2
- SCRN3 | c.408del p.K136Nfs*22 | Frame Shift Del (DEL) | VAF 31/105 reads (30%) | called by mutect2, pindel, varscan2
- SPIDR | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 255/647 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBC1D9 | c.834dup p.V279Sfs*7 | Frame Shift Ins (INS) | VAF 137/419 reads (33%) | called by mutect2, pindel, varscan2
- TCP1 | c.308del p.N103Mfs*5 | Frame Shift Del (DEL) | VAF 29/91 reads (32%) | called by mutect2, pindel, varscan2
- TMEM47 | c.497del p.G166Vfs*7 | Frame Shift Del (DEL) | VAF 81/211 reads (38%) | called by mutect2, pindel, varscan2
- TNRC6A | c.5760del p.T1921Pfs*93 | Frame Shift Del (DEL) | VAF 118/358 reads (33%) | called by mutect2, pindel, varscan2
- TRAPPC11 | c.2567_2568del p.Y856Cfs*10 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | called by pindel, varscan2
- TRBV28 | c.138G>T p.M46I | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- TRPV1 | c.526del p.L176Cfs*12 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | called by mutect2, pindel, varscan2
- USP18 | c.116_117del p.E39Afs*28 | Frame Shift Del (DEL) | VAF 75/233 reads (32%) | called by pindel, varscan2
- VTA1 | c.848dup p.L283Ffs*4 | Frame Shift Ins (INS) | VAF 41/122 reads (34%) | called by mutect2, pindel, varscan2
- WDR41 | c.1298del p.N433Mfs*11 | Frame Shift Del (DEL) | VAF 57/180 reads (32%) | called by mutect2, pindel, varscan2
- ZNF131 | c.979del p.I327Ffs*45 (on ENST00000509156 / NM_001330707.2; = p.I293Ffs*45 on NM_003432.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 27/89 reads (30%) | called by mutect2, pindel, varscan2
- ZNF395 | c.706del p.Q236Rfs*41 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | called by mutect2, varscan2
- ZNF644 | c.1706del p.K569Rfs*4 | Frame Shift Del (DEL) | VAF 76/234 reads (32%) | called by mutect2, pindel, varscan2
- ACBD5 | c.996A>G p.P332= (on ENST00000375888 / NM_001352568.1; = p.P323= on NM_145698.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 44/190 reads (23%) | catalogued as COSV101022466; called by muse, mutect2, varscan2
- ACTL9 | c.687C>T p.T229= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as rs1353609192, COSV61006030; called by muse, mutect2
- ADAMTSL4 | c.2814A>G p.V938= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs777740812, COSV55000656; called by muse, mutect2, varscan2
- ALPK3 | c.2358T>C p.H786= | Silent (SNP) | VAF 44/126 reads (35%) | catalogued as rs1371514314, COSV51934308; called by muse, mutect2, varscan2
- ANXA8L1 | c.279G>A p.P93= | Silent (SNP) | VAF 55/303 reads (18%) | catalogued as rs1315968312; called by muse, mutect2, varscan2
- ARHGAP31 | c.3525C>T p.R1175= | Silent (SNP) | VAF 123/272 reads (45%) | catalogued as rs750550661, COSV51790994; called by muse, mutect2, varscan2
- ARMC9 | c.807C>A p.V269= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV63021258; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1365A>G p.S455= | Silent (SNP) | VAF 151/406 reads (37%) | catalogued as COSV63438143; called by muse, mutect2, varscan2
- B4GALNT2 | c.1240C>T p.L414= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV55926497; called by muse, mutect2, varscan2
- BCL11A | c.507C>T p.H169= (on ENST00000335712 / NM_001365609.1; = p.H203= on NM_018014.4) | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as rs1405736110, COSV59624224, COSV59624844; called by muse, mutect2, varscan2
- BLVRA | c.876C>T p.C292= | Silent (SNP) | VAF 80/187 reads (43%) | catalogued as COSV55514631; called by muse, mutect2, varscan2
- BNC2 | c.2712G>A p.S904= | Silent (SNP) | VAF 58/155 reads (37%) | catalogued as rs747322250, COSV66166881; called by muse, mutect2, varscan2
- CACNA1C | c.2766G>T p.P922= | Silent (SNP) | VAF 49/140 reads (35%) | catalogued as COSV59726318; called by muse, mutect2, varscan2
- CAMKV | c.714C>A p.R238= | Silent (SNP) | VAF 64/150 reads (43%) | catalogued as rs1010662195, COSV56556031; called by muse, mutect2, varscan2
- CAPN5 | c.1587T>C p.T529= (on ENST00000456580; = p.T489= on NM_004055.5) | Silent (SNP) | VAF 41/106 reads (39%) | catalogued as COSV53688489; called by muse, mutect2, varscan2
- CAPN6 | c.102T>C p.P34= | Silent (SNP) | VAF 83/216 reads (38%) | catalogued as COSV60695252; called by muse, mutect2, varscan2
- CCDC110 | c.1257C>T p.S419= | Silent (SNP) | VAF 58/156 reads (37%) | catalogued as rs776982244, COSV56870488; called by muse, mutect2
- CCDC130 | c.168C>T p.C56= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV55583239; called by muse, mutect2, varscan2
- CCT2 | c.1113T>C p.C371= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV54740364; called by muse, mutect2
- CELSR2 | c.5740C>A p.R1914= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV54773274; called by muse, mutect2, varscan2
- CHD3 | c.4425C>T p.A1475= | Silent (SNP) | VAF 157/430 reads (37%) | catalogued as rs1236440954, COSV57875923; called by muse, mutect2, varscan2
- CHD7 | c.1155G>A p.Q385= | Silent (SNP) | VAF 101/273 reads (37%) | catalogued as COSV71111397; called by muse, mutect2, varscan2
- COL12A1 | c.5979G>A p.R1993= | Silent (SNP) | VAF 95/231 reads (41%) | catalogued as COSV59397343, COSV59398120; called by muse, mutect2, varscan2
- COL22A1 | c.1785G>A p.K595= | Silent (SNP) | VAF 54/133 reads (41%) | catalogued as COSV57339944; called by muse, mutect2, varscan2
- CORT | c.24G>C p.L8= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV57630733; called by muse, mutect2, varscan2
- CRTC3 | c.1140C>T p.S380= | Silent (SNP) | VAF 143/368 reads (39%) | catalogued as rs372403240; called by muse, mutect2, varscan2
- CSMD1 | c.5616C>T p.S1872= (on ENST00000520002; = p.S1871= on NM_033225.6) | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as rs186294991, COSV59360664; called by muse, mutect2, varscan2
- CSMD3 | c.3582C>T p.I1194= (on ENST00000297405 / NM_001363185.1; = p.I1090= on NM_052900.3) | Silent (SNP) | VAF 65/169 reads (38%) | catalogued as rs201515007, COSV52233054; called by muse, mutect2, varscan2
- CUEDC2 | c.744C>A p.I248= | Silent (SNP) | VAF 133/479 reads (28%) | catalogued as COSV50046713; called by muse, mutect2, varscan2
- DCAF1 | c.4374T>C p.D1458= | Silent (SNP) | VAF 43/101 reads (43%) | catalogued as COSV60043347; called by muse, mutect2, varscan2
- DCAF10 | c.546G>A p.V182= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV54288567; called by muse, mutect2, varscan2
- DCAF7 | c.768C>T p.C256= | Silent (SNP) | VAF 80/228 reads (35%) | catalogued as COSV60407726; called by muse, mutect2, varscan2
- DIS3 | c.2088A>G p.P696= | Silent (SNP) | VAF 72/193 reads (37%) | catalogued as COSV66706754; called by muse, mutect2, varscan2
- DNM1 | c.2586C>T p.F862= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as rs560349998, COSV57851594; called by muse, mutect2, varscan2
- DPP8 | c.558T>C p.I186= (on ENST00000341861 / NM_001320875.2; = p.I170= on NM_017743.6) | Silent (SNP) | VAF 129/298 reads (43%) | catalogued as COSV55679304; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2193C>T p.R731= | Silent (SNP) | VAF 47/125 reads (38%) | catalogued as rs200245984; called by muse, mutect2, varscan2
- EEF1G | c.808C>T p.L270= | Silent (SNP) | VAF 61/146 reads (42%) | catalogued as rs1317269597, COSV61321881; called by muse, mutect2, varscan2
- ELOVL5 | c.834T>C p.N278= | Silent (SNP) | VAF 68/151 reads (45%) | catalogued as COSV58651020; called by muse, mutect2, varscan2
- EP400 | c.1290G>A p.E430= | Silent (SNP) | VAF 43/93 reads (46%) | catalogued as COSV57774390; called by muse, mutect2, varscan2
- EPS8L1 | c.1113G>A p.R371= (on ENST00000201647 / NM_133180.3; = p.R244= on NM_017729.3) | Silent (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- EXO1 | c.432C>T p.C144= | Silent (SNP) | VAF 53/238 reads (22%) | catalogued as rs756050889, COSV62217840; called by muse, mutect2, varscan2
- EXOSC7 | c.687G>A p.S229= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs1157054263, COSV55555815; called by muse, mutect2, varscan2
- FAM13A | c.42G>A p.A14= | Silent (SNP) | VAF 75/186 reads (40%) | catalogued as rs554336218, COSV52003791; called by muse, mutect2, varscan2
- FAT1 | c.11742G>T p.V3914= | Silent (SNP) | VAF 63/131 reads (48%) | catalogued as COSV71674446; called by muse, mutect2, varscan2
- FAT1 | c.7113C>T p.S2371= | Silent (SNP) | VAF 64/162 reads (40%) | catalogued as rs751674475, COSV71674447; called by muse, mutect2, varscan2
- FBLN1 | c.804T>C p.S268= | Silent (SNP) | VAF 17/201 reads (8%) | catalogued as COSV53048591; called by muse, mutect2
- FMN2 | c.474G>A p.P158= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs1198977248, COSV60417397; called by muse, mutect2
- GAB1 | c.771C>T p.S257= | Silent (SNP) | VAF 46/260 reads (18%) | catalogued as COSV53757151; called by muse, mutect2, varscan2
- GABRG2 | c.600T>C p.D200= | Silent (SNP) | VAF 48/123 reads (39%) | catalogued as COSV62718646; called by muse, mutect2, varscan2
- GNA13 | c.1128A>G p.L376= | Silent (SNP) | VAF 47/123 reads (38%) | catalogued as rs1294333148, COSV71474803; called by muse, mutect2, varscan2
- GRIK2 | c.1938C>T p.I646= | Silent (SNP) | VAF 43/123 reads (35%) | catalogued as rs1160219540, COSV59741039; called by muse, mutect2, varscan2
- HID1 | c.519C>T p.D173= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs774796422, COSV59351635; called by muse, mutect2, varscan2
- HSD11B1 | c.861C>T p.D287= | Silent (SNP) | VAF 69/281 reads (25%) | catalogued as COSV54827814; called by muse, mutect2, varscan2
- HSPA2 | c.498G>A p.T166= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV55969864; called by muse, mutect2, varscan2
- IARS2 | c.1458G>A p.T486= | Silent (SNP) | VAF 36/121 reads (30%) | catalogued as rs749564194, COSV56960257; called by muse, varscan2
- IL1RL2 | c.615G>A p.Q205= | Silent (SNP) | VAF 61/162 reads (38%) | catalogued as COSV51815836; called by muse, mutect2, varscan2
- ITPR3 | c.1575G>A p.P525= | Silent (SNP) | VAF 62/145 reads (43%) | catalogued as rs1441809502, COSV65405560; called by muse, mutect2, varscan2
- KCNK16 | c.735G>A p.A245= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs142567800; called by muse, mutect2
- KCNU1 | c.3312A>G p.Q1104= | Silent (SNP) | VAF 203/549 reads (37%) | catalogued as COSV67756601; called by muse, mutect2, varscan2
- KDM6A | c.2289C>T p.S763= | Silent (SNP) | VAF 60/182 reads (33%) | catalogued as COSV65040970; called by muse, mutect2, varscan2
- KNOP1 | c.1302C>T p.L434= | Silent (SNP) | VAF 64/159 reads (40%) | catalogued as rs759086960, COSV54928489; called by muse, mutect2, varscan2
- LDB3 | c.417G>A p.R139= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV53942637; called by muse, mutect2, varscan2
- LENG1 | c.222C>T p.G74= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as COSV55363980; called by muse, mutect2, varscan2
- LOXL4 | c.1884C>T p.L628= | Silent (SNP) | VAF 29/108 reads (27%) | catalogued as COSV53257113; called by muse, mutect2, varscan2
- LRIT1 | c.42G>A p.A14= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs202166415; called by muse, mutect2, varscan2
- LRP6 | c.4674T>C p.S1558= | Silent (SNP) | VAF 81/199 reads (41%) | catalogued as COSV53788444; called by muse, mutect2, varscan2
- LRRC34 | c.648C>T p.D216= | Silent (SNP) | VAF 41/100 reads (41%) | catalogued as COSV57186396; called by muse, mutect2, varscan2
- MAD1L1 | c.1515C>T p.V505= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs747221108, COSV56236502; called by muse, mutect2, varscan2
- MAN2A1 | c.1411C>T p.L471= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV54852592; called by muse, mutect2, varscan2
- MARF1 | c.5112G>A p.S1704= | Silent (SNP) | VAF 5/112 reads (4%) | catalogued as rs372430064; called by muse, mutect2
- MCM3AP | c.4794C>T p.G1598= | Silent (SNP) | VAF 66/155 reads (43%) | catalogued as rs772560798, COSV52440514; called by muse, mutect2, varscan2
- MCM4 | c.2530C>T p.L844= | Silent (SNP) | VAF 6/122 reads (5%) | catalogued as COSV50624252; called by muse, mutect2
- MECOM | c.504G>A p.T168= (on ENST00000468789 / NM_001105078.4; = p.T356= on NM_004991.4) | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs770726960, COSV52965824; called by muse, mutect2, varscan2
- MPIG6B | c.342C>T p.D114= | Silent (SNP) | VAF 75/393 reads (19%) | catalogued as COSV65389720; called by muse, mutect2, varscan2
- MYH1 | c.3210A>G p.T1070= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV56849774; called by muse, mutect2
- MYH13 | c.1920C>T p.G640= | Silent (SNP) | VAF 51/147 reads (35%) | catalogued as rs747309262, COSV52830918; called by muse, mutect2, varscan2
- MYO1E | c.726C>T p.G242= | Silent (SNP) | VAF 68/171 reads (40%) | catalogued as rs775975506, COSV55688601; called by muse, mutect2, varscan2
- NCKAP1L | c.1515G>A p.L505= | Silent (SNP) | VAF 143/299 reads (48%) | catalogued as rs751669794, COSV53207726; called by muse, mutect2, varscan2
- NDUFS3 | c.432G>A p.K144= | Silent (SNP) | VAF 56/134 reads (42%) | catalogued as COSV55455003, COSV99772451; called by muse, mutect2, varscan2
- NPAP1 | c.2796A>G p.S932= | Silent (SNP) | VAF 43/107 reads (40%) | catalogued as COSV61507744; called by muse, mutect2, varscan2
- NPBWR1 | c.135G>T p.A45= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV58696427; called by muse, mutect2, varscan2
- NPHS1 | c.904C>T p.L302= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV62288245; called by muse, mutect2, varscan2
- OR2G3 | c.15T>C p.N5= | Silent (SNP) | VAF 141/484 reads (29%) | catalogued as COSV60681906; called by muse, varscan2
- OR2G3 | c.63T>A p.P21= | Silent (SNP) | VAF 168/612 reads (27%) | catalogued as COSV60681911; called by muse, varscan2
- OR56A3 | c.918A>G p.G306= | Silent (SNP) | VAF 155/407 reads (38%) | catalogued as COSV61569226; called by muse, mutect2, varscan2
- OTOGL | c.1404T>C p.V468= (on ENST00000547103; = p.V459= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs758360453, COSV72006719; called by muse, mutect2, varscan2
- PATJ | c.2691C>A p.A897= | Silent (SNP) | VAF 98/297 reads (33%) | catalogued as COSV57163735; called by muse, mutect2, varscan2
- PCDHGB7 | c.85C>T p.L29= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV53961758; called by muse, mutect2, varscan2
- PDE3B | c.1620T>C p.T540= | Silent (SNP) | VAF 40/95 reads (42%) | catalogued as COSV56384672; called by muse, mutect2, varscan2
- PHLDA1 | c.603G>A p.Q201= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as rs371223910, COSV56997044; called by muse, mutect2, varscan2
- PIK3CG | c.870C>T p.F290= | Silent (SNP) | VAF 42/115 reads (37%) | catalogued as rs760413478, COSV63249073; called by muse, mutect2, varscan2
- PIP4K2A | c.372C>T p.N124= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as rs191394168; called by muse, mutect2, varscan2
- PLCG2 | c.1993C>A p.R665= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV63870401; called by muse, mutect2, varscan2
- POGZ | c.279C>T p.N93= | Silent (SNP) | VAF 109/376 reads (29%) | catalogued as COSV55036585; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.219C>T p.C73= | Silent (SNP) | VAF 46/116 reads (40%) | catalogued as rs138161374; called by muse, varscan2
- PPM1K | c.1053A>G p.K351= | Silent (SNP) | VAF 39/93 reads (42%) | catalogued as COSV55796130; called by muse, mutect2, varscan2
- PRB4 | c.261C>T p.N87= | Silent (SNP) | VAF 294/2544 reads (12%) | catalogued as COSV54397322; called by muse, varscan2
- PRPF39 | c.975G>A p.E325= | Silent (SNP) | VAF 48/150 reads (32%) | catalogued as COSV63276938; called by muse, mutect2, varscan2
- PSME4 | c.4593T>C p.P1531= | Silent (SNP) | VAF 85/201 reads (42%) | catalogued as COSV66365491; called by muse, mutect2, varscan2
- PTPRS | c.822A>G p.P274= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV53622381; called by muse, mutect2, varscan2
- PXDN | c.2889G>A p.E963= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV53236258; called by muse, mutect2, varscan2
- PXN | c.1539C>T p.S513= (on ENST00000228307 / NM_001080855.3; = p.S479= on NM_002859.4) | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV57219187; called by muse, mutect2, varscan2
- QRICH2 | c.4230C>T p.D1410= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs747795649, COSV53153978; called by muse, mutect2, varscan2
- RAB31 | c.111T>C p.P37= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as rs1465154379, COSV71261710; called by muse, mutect2, varscan2
- RELT | c.1075C>A p.R359= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV50361481; called by muse, mutect2, varscan2
- RFX5 | c.654G>A p.R218= | Silent (SNP) | VAF 15/240 reads (6%) | catalogued as COSV51839513; called by muse, mutect2
- SEPTIN9 | c.1386C>T p.T462= (on ENST00000427177 / NM_001113491.2; = p.T444= on NM_006640.4) | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as rs377093783, COSV61204276; called by muse, mutect2, varscan2
- SFTPA2 | c.135C>T p.D45= | Silent (SNP) | VAF 39/164 reads (24%) | catalogued as rs370764679, COSV100958881; called by muse, mutect2, varscan2
- SH3TC1 | c.3879C>T p.D1293= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV55284787; called by muse, mutect2, varscan2
- SLC22A2 | c.258A>G p.P86= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV65266686; called by muse, mutect2
- SLC26A7 | c.738G>A p.E246= | Silent (SNP) | VAF 53/122 reads (43%) | catalogued as COSV52594915; called by muse, mutect2, varscan2
- SLC38A5 | c.1062G>A p.L354= | Silent (SNP) | VAF 6/87 reads (7%) | catalogued as rs1385474826, COSV58334453; called by muse, mutect2
- SLC39A9 | c.12C>T p.F4= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV50362689; called by muse, varscan2
- SLC4A5 | c.1776C>T p.F592= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as rs148607545; called by muse, mutect2, varscan2
- SMG1 | c.5427C>T p.H1809= | Silent (SNP) | VAF 60/151 reads (40%) | catalogued as rs755842672, COSV67171885; called by muse, mutect2, varscan2
- SNAP91 | c.1887G>A p.S629= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs763210208, COSV52123884; called by muse, mutect2, varscan2
- STARD3 | c.1014G>A p.A338= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs141159762; called by muse, mutect2, varscan2
- STYXL2 | c.132A>G p.A44= | Silent (SNP) | VAF 78/342 reads (23%) | catalogued as COSV54805936; called by muse, mutect2, varscan2
- SUN1 | c.2250C>T p.F750= (on ENST00000405266 / NM_001367651.1; = p.F630= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 53/126 reads (42%) | catalogued as rs777094056, COSV67449918; called by muse, mutect2, varscan2
- SYNE2 | c.4734A>G p.E1578= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV59953194; called by muse, mutect2, varscan2
- SYNGR1 | c.312C>T p.A104= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs756458157, COSV53368493; called by muse, mutect2, varscan2
- SYNJ2 | c.2413C>T p.L805= | Silent (SNP) | VAF 68/156 reads (44%) | catalogued as COSV62897961; called by muse, mutect2, varscan2
- SYNM | c.4665T>C p.N1555= (on ENST00000336292 / NM_145728.3; = p.N1243= on NM_015286.6) | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as rs781812880, COSV50442162; called by muse, mutect2, varscan2
- SZT2 | c.2179C>T p.L727= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100986880; called by muse, mutect2, varscan2
- TBC1D2B | c.1026G>A p.L342= | Silent (SNP) | VAF 63/149 reads (42%) | catalogued as COSV56042634; called by muse, mutect2, varscan2
- TCIRG1 | c.1104G>A p.T368= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs1254116216, COSV55835858; called by muse, mutect2, varscan2
- TDRD3 | c.1092T>C p.S364= | Silent (SNP) | VAF 63/150 reads (42%) | catalogued as COSV52157622; called by muse, mutect2, varscan2
- TENT5C | c.1164G>T p.L388= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV65616493; called by muse, varscan2
- TKTL2 | c.591G>A p.E197= | Silent (SNP) | VAF 58/140 reads (41%) | catalogued as COSV54919270; called by muse, mutect2, varscan2
- TMEM108 | c.567C>T p.G189= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV58872024; called by muse, mutect2, varscan2
- TMEM132E | c.1356G>A p.E452= (on ENST00000321639; = p.E542= on NM_001304438.2) | Silent (SNP) | VAF 45/135 reads (33%) | catalogued as COSV58697556; called by muse, mutect2, varscan2
- TRIM7 | c.1533T>C p.P511= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV51243061; called by muse, mutect2, varscan2
- TTC12 | c.1434C>T p.C478= | Silent (SNP) | VAF 9/170 reads (5%) | catalogued as COSV59098146; called by muse, mutect2
- TTLL3 | c.2058G>A p.A686= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs201406169, COSV59614603; called by muse, mutect2, varscan2
- TUBA3C | c.144C>A p.S48= | Silent (SNP) | VAF 40/113 reads (35%) | catalogued as COSV67139398; called by muse, mutect2, varscan2
- TYRO3 | c.2220G>A p.E740= | Silent (SNP) | VAF 28/190 reads (15%) | catalogued as COSV55483755; called by muse, mutect2
- URB2 | c.3390G>A p.Q1130= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV50994911; called by muse, mutect2, varscan2
- WNT3 | c.642C>T p.S214= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs983198653, COSV56645368; called by muse, mutect2, varscan2
- WWOX | c.777C>A p.S259= | Silent (SNP) | VAF 123/311 reads (40%) | catalogued as COSV68355821; called by muse, mutect2, varscan2
- XIRP1 | c.924C>T p.R308= | Silent (SNP) | VAF 59/118 reads (50%) | catalogued as COSV61138883; called by muse, mutect2, varscan2
- ZBTB12 | c.105G>T p.V35= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV64993912; called by muse, mutect2, varscan2
- ZNF14 | c.1422C>A p.P474= | Silent (SNP) | VAF 120/324 reads (37%) | catalogued as COSV59849879; called by muse, mutect2, varscan2
- ZNF155 | c.1152C>T p.S384= | Silent (SNP) | VAF 182/463 reads (39%) | catalogued as COSV54207097, COSV99525850; called by muse, mutect2, varscan2
- ZNF266 | c.1461T>C p.T487= | Silent (SNP) | VAF 64/186 reads (34%) | catalogued as COSV63222297; called by muse, mutect2, varscan2
- ZNF7 | c.594C>T p.C198= | Silent (SNP) | VAF 41/114 reads (36%) | catalogued as rs146614064, COSV57383307; called by muse, mutect2, varscan2
- ZNF700 | c.1839T>C p.T613= | Silent (SNP) | VAF 121/356 reads (34%) | catalogued as COSV54312858; called by muse, mutect2, varscan2
- ZNF750 | c.1281C>T p.C427= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as rs747644446, COSV53960594; called by muse, mutect2, varscan2
- ZSCAN5B | c.1311G>A p.R437= | Silent (SNP) | VAF 92/227 reads (41%) | catalogued as COSV62000302; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445639 G>T | 3'Flank (SNP) | VAF 24/47 reads (51%) | called by muse, mutect2, varscan2
- FOXP1 | c.180+201C>A | Intron (SNP) | VAF 31/85 reads (36%) | catalogued as COSV59521925; called by muse, mutect2, varscan2
- LRMDA | c.131+114022G>A | Intron (SNP) | VAF 9/33 reads (27%) | catalogued as COSV66021446; called by muse, mutect2, varscan2
- LRRC10 | c.-1C>T | 5'UTR (SNP) | VAF 9/19 reads (47%) | catalogued as COSV100825441; called by muse, mutect2, varscan2
- MBD2 | c.542+1674C>T | Intron (SNP) | VAF 16/45 reads (36%) | catalogued as COSV99839903; called by muse, mutect2, varscan2
- PRR22 | c.194-15G>A | Intron (SNP) | VAF 9/14 reads (64%) | catalogued as rs764295775, COSV57832152; called by muse, mutect2, varscan2
- RMDN2 | c.452+21918del | Intron (DEL) | VAF 82/252 reads (33%) | catalogued as rs761706403; called by mutect2, varscan2
- TMPRSS11F | c.1015+1809del | Intron (DEL) | VAF 143/405 reads (35%) | called by mutect2, pindel, varscan2
- WNK1 | c.2140-2650C>T | Intron (SNP) | VAF 53/109 reads (49%) | catalogued as COSV60035163; called by muse, mutect2, varscan2
